Gene-level copy-number profile of tumor specimen TCGA-06-0173-01A from TCGA case TCGA-06-0173, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.7 years (26,549 days).
Specimen TCGA-06-0173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1082e494-5cf0-4988-8430-9874a332fe6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0173-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66988a94-8285-4d5e-9df7-2a3199f57f76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,881; copy number 2: 49,300; copy number 3: 7,512; copy number 4: 25; copy number 6: 7; copy number 10: 21; copy number 13: 2; copy number 25: 7; copy number 28: 17; copy number 33: 36; copy number 34: 6; copy number 37: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0173-01A-01D-0236-01): tumor purity 0.86, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,513,220–13,825,079, 7 genes, copy number 6: AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:242,882,066–244,641,177, 33 genes, copy number 33 (within-gene range 2–33): AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE.
- chr7:54,542,325–55,344,958, 16 genes, copy number 28: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr12:45,444,766–45,610,620, 3 genes, copy number 37: AC063924.1, AC079950.1, U6.
- chr12:46,183,063–46,270,017, 2 genes, copy number 37 (within-gene range 1–37): SLC38A1, AC025031.3.
- chr12:47,341,614–47,485,722, 7 genes, copy number 25: PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.
- chr12:57,243,453–57,431,005, 3 genes, copy number 10 (within-gene range 4–10): STAC3, AC137834.1, R3HDM2.
- chr12:57,723,761–57,846,729, 18 genes, copy number 10: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:57,906,039–57,959,148, 2 genes, copy number 13 (within-gene range 1–13): ATP23, GIHCG.
- chr12:58,394,596–58,395,138, 1 gene, copy number 28: AC025578.1.
- chr12:65,589,111–65,663,299, 3 genes, copy number 33 (within-gene range 2–33): LINC02454, AC090023.2, PCNPP3.
- chr12:68,746,125–68,850,686, 6 genes, copy number 34: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.

Autosomal genes at a single copy (total copy number 1): 2,881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
